Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A8Z8, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A8Z8-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

Carcinoma, squamous cell
8070/3

Site: Larynx, NOS C32.9

fw 4/30/14

Results

SURGICAL PATHOLOGY EXAM (Order

Case Report

Case Report

Surgical Pathology Report

Case:

Authorizing Provider:

Ordering Provider:

Ordering Location:

Collected:

Pathologist:

Received:

Signed Out:

Specimens: A) - Larynx

B) - Larynx

Final Diagnosis

A. Larynx, right aryepiglottic fold, biopsy:

- Invasive squamous cell carcinoma, moderately differentiated.

B. Larynx, left aryepiglottic fold, biopsy:

- Invasive squamous cell carcinoma, moderately differentiated,
extending into adjacent cartilage.

Clinical Information

supra glottis mass

[page 2 of 4]
Gross Description

A

Specimen A is received in formalin. Both the original label and the generated label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SITE INDICATED ON THE CONTAINER LABEL: tumor right AE fold

The specimen consists of an epithelialized lobulated tan-pink tissue measuring 2.0 x 0.6 x 0.6 cm. Cut surface is rubbery.

The specimen is entirely submitted in cassette labeled A1.

B

Specimen B is received in formalin. Both the original label and the generated label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SITE INDICATED ON THE CONTAINER LABEL: tumor left AE fold

The specimen consists of multiple lobulated tissue fragments measuring 1.5 x 0.8 x 0.6 cm in aggregate dimension. Cut surfaces are rubbery.

The specimen is entirely submitted in cassette labeled B1.

Dictated by

[page 3 of 4]
Authorizing Provider Information

Name: Fax:

Phone: Pager:

PDF Results and Scans

Lab Information

Lab Lab Director

Lab Collection Information

Collection Date and Time

Noted		

[page 4 of 4]
SURGICAL PATHOLOGY EXAM

Pathology and Cytology

Authorizing:

Department:

Date:

Released By:

Source: NCI Genomic Data Commons file 476e87cf-07dc-4d6b-96f3-a5fccab96118 (TCGA-QK-A8Z8.7B41E5CC-FC4F-405D-95AC-E127BEF7F881.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).